TCGA case TCGA-SH-A9CT — Mesothelioma (TCGA-MESO)
Open-access clinical record from the NCI Genomic Data Commons (Data Release 46.0 - August 10, 2026), part of The Cancer Genome Atlas (TCGA). Disease type: Mesothelial Neoplasms; Primary site: Heart, mediastinum, and pleura; Tissue source site: Papworth Hospital. Index date (day 0 for every day count below): diagnosis.
https://portal.gdc.cancer.gov/cases/ef8b1e2c-9623-44fe-b591-8c8e6a232da5

Demographics
Sex at birth: male; Race: white; Ethnicity: not hispanic or latino; Country of residence at enrollment: United Kingdom; Age at index: 67 years; Vital status: Dead; Days to death: 449 days (1.2 years).

Diagnoses (2)
1. Epithelioid mesothelioma, malignant (the primary disease): ICD-O-3 morphology code: 9052/3; ICD-10 code: C45.0; Tissue or organ of origin: Pleura, NOS; Site of resection or biopsy: Pleura, NOS; Laterality: Right; Classification of tumor: primary; Age at diagnosis: 67.2 years (24,528 days); Year of diagnosis: 2013; Method of diagnosis: Imaging; AJCC staging edition: 7th; AJCC pathologic T: T2; AJCC pathologic N: N0; AJCC pathologic M: M0; AJCC pathologic stage: Stage II; Prior malignancy: no; Synchronous malignancy: No; Prior treatment: No; Days to last follow up: 449 days (1.2 years).
   Pathology details: Consistent pathology review: Yes.
   Treatment given: Treatment type: Chemotherapy; Therapeutic agents: Cisplatin + Pemetrexed; Days to treatment start: 46 days; Days to treatment end: 155 days; Treatment outcome: Partial Response.
   Recorded as not given: Pleurodesis, NOS, prior to procurement; adjuvant Radiation Therapy, NOS.
2. Diagnosis record without a diagnosis name: Tissue or organ of origin: Thorax, NOS; Tumor of origin: diagnosis 1 of this record; Age at diagnosis: 67.3 years (24,571 days); Days to diagnosis: 43 days; Prior treatment: Yes.

Follow-up (5 entries)
- Day 43 (post initial treatment): Progression or recurrence: Yes; Progression or recurrence anatomic site: Thorax, NOS.
- Days to follow up: 256 days; Disease response: With Tumor.
- Days to follow up: 449 days (1.2 years); Disease response: With Tumor.
- ECOG performance status: 1; Timepoint: Preoperative.
- Karnofsky performance status: 0.

Molecular and laboratory tests
- Creatinine 126 mg/dL [Blood test normal range lower: 35; Blood test normal range upper: 125].

Exposures
- Occupation duration years: 45; Occupation type: Building Frame and Related Trades Workers.

Biospecimens (3 samples; slide percentages are pathologist estimates recorded by GDC per slide)
- Sample TCGA-SH-A9CT-01A: Sample type: Primary Tumor; Tissue type: Tumor; Tumor descriptor: Primary; Specimen type: Solid Tissue; Preservation method: OCT; Initial weight: 570 mg.
  Slide TCGA-SH-A9CT-01A-01-TSA: Section location: Top; Percent tumor cells: 80; Percent tumor nuclei: 80; Percent normal cells: 0; Percent necrosis: 0; Percent stromal cells: 20; Percent lymphocyte infiltration: 4; Percent monocyte infiltration: 1; Percent neutrophil infiltration: 4.
- Sample TCGA-SH-A9CT-01Z: Sample type: Primary Tumor; Tissue type: Tumor; Tumor descriptor: Primary; Specimen type: Solid Tissue; Preservation method: FFPE; Days to sample procurement: 0 days.
- Sample TCGA-SH-A9CT-10A: Sample type: Blood Derived Normal; Tissue type: Normal; Specimen type: Peripheral Blood NOS.

Additional fields from the legacy TCGA clinical forms (Biospecimen Core Resource XML)
- Enrollment form: Prospective collection: No; Retrospective collection: Yes; History neoadjuvant treatment: No; Pleurodesis performed prior: No; Tumor status: With tumor; Primary occupation: Other, please specify; Occupation primary: Carpenter; New tumor event diagnosis indicator: No.
- Primary pathology: Submitted tumor site: Pleura; Histologic diagnosis: Epithelioid mesothelioma; Mesothelioma detection method: Thorascopy.
- Follow-up form: Lost to follow-up: No; Tumor status: With tumor; New tumor event diagnosis indicator: Yes.
- Follow-up form, New tumor event: New tumor event site other: Ipsilateral Chest Wall.

Curated follow-up endpoints (TCGA Pan-Cancer Clinical Data Resource, Liu et al., Cell 2018; times are days from initial pathologic diagnosis to the event or to last contact): overall survival: event (deceased), 449 days; disease-specific survival: event (death attributed to the disease, the Clinical Data Resource's approximation), 449 days; progression-free interval: event (progression, recurrence, new primary tumor or death with tumor), 449 days.

Tumor purity and ploidy (ABSOLUTE, TCGA Pan-Cancer Atlas; aliquot TCGA-SH-A9CT-01A-11D-A39Q-01): tumor purity 0.73, ploidy 1.86, whole-genome doublings 0.
